Somatic mutation profile of tumor specimen C3L-06357-54 (aliquot CPT0345500002) from CPTAC case C3L-06357, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 60.4 years (22,055 days).
Specimen C3L-06357-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f625b95a-6305-405c-8df5-8719001561ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06357-50 (Buccal Cell Normal), aliquot CPT0345470003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76f91bbd-4bc4-4e6f-9e12-55d3e84ecec6

The open-access MAF lists 65 somatic variants for this specimen: 39 protein-altering or splice-affecting, 15 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 15, Intron 7, Nonsense Mutation 3, 3'UTR 3, Frame Shift Ins 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 81/105 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.1597G>A p.G533R | Missense Mutation (SNP) | VAF 137/319 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1169320456, COSV100131761; called by muse, mutect2, varscan2
- BEND3 | c.17T>G p.F6C | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.322); catalogued as COSV64682440; called by muse, mutect2, varscan2
- CNTNAP3 | c.2359G>A p.G787R | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1563880650, COSV99905389; called by muse, mutect2, varscan2
- DDX59 | c.180C>A p.C60* | Nonsense Mutation (SNP) | VAF 95/188 reads (51%) | catalogued as COSV58751469; called by muse, mutect2, varscan2
- DNMT3A | c.2012C>T p.T671M | Missense Mutation (SNP) | VAF 113/270 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV53066939; called by muse, mutect2, varscan2
- DOCK2 | c.4771G>T p.V1591L | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.072); catalogued as COSV56940615; called by muse, mutect2, varscan2
- LRFN2 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 141/300 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); catalogued as rs1300496795; called by muse, mutect2, varscan2
- NRG1 | c.1364C>T p.P455L (on ENST00000405005 / NM_013964.5; = p.P460L on NM_013956.5) | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs779333674; called by muse, mutect2, varscan2
- RDX | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 122/578 reads (21%) | catalogued as rs1308348441, COSV100563157; called by muse, mutect2, varscan2
- SLC44A5 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs1473846869; called by muse, mutect2, varscan2
- UNC13C | c.5816A>G p.Q1939R | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs1293783198; called by muse, mutect2, varscan2
- UPP2 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1014463367; called by muse, mutect2, varscan2
- ATF4 | c.12_13insTC p.F6Afs*3 | Frame Shift Ins (INS) | VAF 11/22 reads (50%) | called by mutect2, pindel, varscan2
- ATG9A | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CCDC93 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CEP295 | c.1475T>G p.V492G | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CHPF | c.1147T>C p.S383P | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- COQ3 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DMD | c.878A>G p.K293R | Missense Mutation (SNP) | VAF 105/118 reads (89%) | SIFT tolerated (0.51); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- IMPA2 | c.155A>C p.D52A | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KMT2C | c.8C>G p.S3W | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.561); called by muse, varscan2
- LTN1 | c.4846A>G p.T1616A | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- LTO1 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MAX | c.70A>T p.K24* | Nonsense Mutation (SNP) | VAF 124/151 reads (82%) | called by muse, mutect2, varscan2
- MORC4 | c.1283A>C p.Q428P | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- MUC5AC | c.15887G>T p.C5296F | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUMBL | c.1160-2A>G p.X387_splice | Splice Site (SNP) | VAF 25/70 reads (36%) | called by mutect2, varscan2
- OR2T34 | c.430A>T p.R144W | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- PLA2R1 | c.2455dup p.Y819Lfs*19 | Frame Shift Ins (INS) | VAF 34/96 reads (35%) | called by mutect2, pindel
- SEH1L | c.146G>T p.C49F | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SLC9B2 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SYNE1 | c.20963A>G p.D6988G (on ENST00000367255 / NM_182961.4; = p.D6917G on NM_033071.3) | Missense Mutation (SNP) | VAF 130/290 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TCHHL1 | c.2173G>C p.D725H | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TOE1 | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 136/247 reads (55%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- UGGT2 | c.1289T>G p.I430S | Missense Mutation (SNP) | VAF 54/68 reads (79%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- VCX2 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); called by mutect2, varscan2
- ZCWPW2 | c.565T>C p.S189P | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ZNF219 | c.1822A>G p.K608E | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- A1CF | c.138T>A p.G46= | Silent (SNP) | VAF 71/169 reads (42%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.1956C>T p.L652= | Silent (SNP) | VAF 93/212 reads (44%) | catalogued as COSV51436980; called by muse, mutect2, varscan2
- ASPG | c.1113A>G p.S371= | Silent (SNP) | VAF 108/200 reads (54%) | called by muse, mutect2, varscan2
- CFAP74 | c.3825G>A p.L1275= | Silent (SNP) | VAF 63/162 reads (39%) | catalogued as rs1434984645; called by muse, mutect2, varscan2
- FAT4 | c.4125C>G p.A1375= | Silent (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 53/61 reads (87%) | catalogued as rs376111067; called by muse, mutect2, varscan2
- IGKJ5 | c.27A>G p.R9= | Silent (SNP) | VAF 37/43 reads (86%) | catalogued as rs543544147; called by muse, varscan2
- IGLV3-1 | c.81C>G p.P27= | Silent (SNP) | VAF 120/344 reads (35%) | catalogued as rs761499455; called by muse, mutect2
- MAN2A2 | c.1908A>C p.P636= | Silent (SNP) | VAF 102/270 reads (38%) | called by muse, mutect2, varscan2
- NELL1 | c.1749C>T p.D583= | Silent (SNP) | VAF 79/233 reads (34%) | catalogued as rs758011669, COSV100117908; called by muse, mutect2, varscan2
- OR51S1 | c.495G>T p.L165= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs745993003, COSV59057547; called by muse, mutect2
- PAK4 | c.1329C>T p.S443= | Silent (SNP) | VAF 62/131 reads (47%) | catalogued as rs141004307; called by muse, mutect2, varscan2
- PPP1R12B | c.2580G>C p.R860= | Silent (SNP) | VAF 60/125 reads (48%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.3987C>T p.D1329= | Silent (SNP) | VAF 96/223 reads (43%) | catalogued as COSV100351035; called by muse, mutect2, varscan2
- TMEM132B | c.546G>T p.L182= | Silent (SNP) | VAF 64/138 reads (46%) | called by muse, mutect2, varscan2
- DNAJB13 | c.335-47G>C | Intron (SNP) | VAF 53/208 reads (25%) | called by muse, mutect2, varscan2
- H2BP2 | n.1062-355C>G | Intron (SNP) | VAF 132/211 reads (63%) | called by muse, mutect2, varscan2
- IFT122 | c.*10T>C | 3'UTR (SNP) | VAF 194/454 reads (43%) | called by muse, mutect2, varscan2
- LIAS | c.758-17T>C | Intron (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- LINC01550 | n.306del | RNA (DEL) | VAF 122/398 reads (31%) | called by mutect2, pindel*, varscan2
- LRATD1 | c.*751G>T | 3'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, varscan2
- PACS1 | c.978+26G>C | Intron (SNP) | VAF 98/186 reads (53%) | called by muse, mutect2, varscan2
- PALLD | c.1965-13064C>T | Intron (SNP) | VAF 101/226 reads (45%) | called by muse, mutect2, varscan2
- RBM39 | c.52-463G>T | Intron (SNP) | VAF 61/178 reads (34%) | called by muse, mutect2, varscan2
- TMEM43 | c.13-539C>T | Intron (SNP) | VAF 22/42 reads (52%) | called by mutect2, varscan2
- XIAP | c.*2536C>G | 3'UTR (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
